Gene-level copy-number profile of tumor specimen TARGET-40-PATMIF-01A from TARGET case TARGET-40-PATMIF, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.0 years (4,383 days).
Specimen TARGET-40-PATMIF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.b39bd627-78f7-5413-aa50-35ae24077b02.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATMIF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate.
https://portal.gdc.cancer.gov/files/4c0f8f8d-7f4b-4730-a28f-becb4747efec

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,132; copy number 1: 2,284; copy number 2: 14,268; copy number 3: 16,946; copy number 4: 12,156; copy number 5: 5,576; copy number 6: 4,176; copy number 7: 1,044; copy number 8: 1,174; copy number 9: 206; copy number 10: 272; copy number 11: 168; copy number 12: 57; copy number 13: 193; copy number 14: 89; copy number 15: 132; copy number 17: 99; copy number 18: 25; copy number 19: 145; copy number 20: 17; copy number 21: 5; copy number 22: 1; copy number 24: 51.

Homozygous deletions (total copy number 0; autosomes only): 611 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr3:105,366,909–120,513,188, 235 genes (broad region; genes not listed).
- chr3:120,684,938–125,679,781, 93 genes (within-gene range 0–2) (broad region; genes not listed).
- chr4:53,286–3,453,108, 113 genes (broad region; genes not listed).
- chr8:144,973,589–145,066,685, 7 genes (within-gene range 0–6): ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:19,507,452–29,318,952, 132 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:103,967,140–104,029,233, 2 genes (within-gene range 0–2): SLK, RN7SL524P.
- chr12:133,079,838–133,214,832, 7 genes (within-gene range 0–3): ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.
- chr16:6,380,476–6,395,578, 1 gene: AC006112.1.
- chr17:41,307,700–41,315,710, 2 genes: KRTAP16-1, KRTAP17-1.
- chr18:79,959,579–80,247,514, 12 genes: AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr22:25,351,418–25,437,823, 4 genes (within-gene range 0–3): LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1.
- chr22:25,455,646–25,479,971, 2 genes: MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,339 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,243,095–20,244,664, 1 gene, copy number 14: LINC01757.
- chr1:77,773,865–80,646,791, 43 genes, copy number 7: ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2, MGC27382, PTGFR, AC096531.1, RNA5SP23, IFI44L, IFI44, AC104837.2, AC104837.1, ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2, AC099671.1, AC098657.1, AC098657.2, AC098657.3, HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781.
- chr1:102,199,739–108,963,484, 64 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:117,929,720–121,580,524, 84 genes, copy number 7 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 18 (within-gene range 5–18): AC244205.1.
- chr2:88,857,161–95,076,900, 144 genes, copy number 8–18 (broad region; genes not listed).
- chr3:87,792,492–89,482,134, 15 genes, copy number 11: HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1.
- chr4:49,203,171–56,033,361, 102 genes, copy number 9–11 (broad region; genes not listed).
- chr4:56,097,390–56,097,504, 1 gene, copy number 11: RNA5SP161.
- chr5:37,379,285–45,895,970, 132 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:36,697,826–71,585,906, 525 genes, copy number 7–24 (broad region; genes not listed).
- chr7:70,972–1,747,954, 55 genes, copy number 9: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:9,082,557–9,851,386, 8 genes, copy number 7: AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1.
- chr8:92,699,742–95,811,254, 72 genes, copy number 10 (broad region; genes not listed).
- chr8:96,370,800–140,635,633, 572 genes, copy number 7–14 (within-gene range 3–14) (broad region; genes not listed).
- chr9:6,413,151–7,961,224, 26 genes, copy number 7–10: UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:8,700,595–9,091,245, 6 genes, copy number 9: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr10:38,247,922–38,333,155, 1 gene, copy number 8 (within-gene range 6–8): AL133217.1.
- chr10:38,356,380–44,310,237, 82 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr10:50,962,993–62,375,166, 86 genes, copy number 9–14 (broad region; genes not listed).
- chr12:28,564,678–29,784,759, 16 genes, copy number 8: AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.
- chr12:33,374,238–37,576,384, 19 genes, copy number 12: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P.
- chr12:38,544,177–41,072,415, 28 genes, copy number 8–12 (within-gene range 6–12): AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr14:18,333,726–19,957,996, 83 genes, copy number 17 (broad region; genes not listed).
- chr14:90,524,564–90,816,479, 1 gene, copy number 7 (within-gene range 5–7): TTC7B.
- chr14:90,642,638–99,535,044, 178 genes, copy number 7 (broad region; genes not listed).
- chr14:99,512,501–99,513,576, 1 gene, copy number 7: AL110504.1.
- chr16:32,951,993–35,912,516, 147 genes, copy number 8–10 (broad region; genes not listed).
- chr17:7,717,354–19,022,595, 373 genes, copy number 7–17 (within-gene range 4–17) (broad region; genes not listed).
- chr17:19,127,535–22,706,703, 176 genes, copy number 7–22 (broad region; genes not listed).
- chr19:19,385,826–23,031,818, 179 genes, copy number 8–15 (broad region; genes not listed).
- chr20:45,416,084–48,827,999, 109 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr21:12,999,676–13,427,773, 9 genes, copy number 8: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3.

Autosomal genes at a single copy (total copy number 1): 2,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
